Somatic mutation profile of tumor specimen C3N-03458-01 (aliquot CPT0246670006) from CPTAC case C3N-03458, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 70.2 years (25,648 days).
Specimen C3N-03458-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8d6793a-e5fb-4688-9f02-93f5fa0d98e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03458-31 (Blood Derived Normal), aliquot CPT0246710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddc8abd7-dac9-46e9-bec0-7f7e6cbaf2f2

The open-access MAF lists 170 somatic variants for this specimen: 124 protein-altering or splice-affecting, 32 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 32, Intron 10, Splice Site 5, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 2, RNA 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 196/448 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACY3 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 143/619 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs368510323; called by muse, mutect2, varscan2
- ALMS1 | c.6317C>T p.P2106L | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as rs765640576; called by muse, mutect2, varscan2
- APOB | c.8200C>T p.P2734S | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.854); catalogued as COSV51928474, COSV51931256; called by muse, mutect2, varscan2
- ARHGEF28 | c.3566G>A p.S1189N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs1197091777; called by muse, varscan2
- ARID1A | c.6160G>C p.E2054Q | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV61378100; called by muse, mutect2
- ARID3B | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs754732175; called by muse, mutect2
- ARSL | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.104); catalogued as rs868508866; called by muse, mutect2, varscan2
- ASTN2 | c.3484G>A p.D1162N (on ENST00000313400 / NM_001365069.1; = p.D1111N on NM_014010.5) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1237046717; called by muse, mutect2, varscan2
- ATP6V1C2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs778432930, COSV99696263; called by muse, mutect2, varscan2
- BMP4 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746984770, COSV55415564; called by muse, mutect2, varscan2
- C15orf61 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs995990624; called by muse, mutect2, varscan2
- CACNA2D4 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.236); catalogued as rs201412060; called by muse, mutect2, varscan2
- CCDC184 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57251823; called by muse, mutect2, varscan2
- CD177 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs749957252; called by muse, mutect2, varscan2
- CDC42BPB | c.643C>G p.R215G | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63476804; called by muse, mutect2, varscan2
- CDH10 | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 84/391 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.75); catalogued as COSV52583310; called by muse, mutect2, varscan2
- CES4A | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769087568; called by muse, mutect2, varscan2
- COL4A4 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61630005; called by muse, mutect2
- CYHR1 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); catalogued as rs1192803561; called by muse, mutect2
- DNAAF5 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372983996; called by muse, mutect2
- DNAH1 | c.4807G>A p.V1603I | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs773102484; called by muse, mutect2, varscan2
- DUOX2 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 109/472 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772940857; called by muse, mutect2, varscan2
- EIF2B3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs776505832, CM152489; called by muse, mutect2, varscan2
- FASN | c.2824C>T p.R942C | Missense Mutation (SNP) | VAF 196/840 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs754621431, COSV60753692; called by muse, varscan2
- FASTKD1 | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs145655228; called by muse, mutect2, varscan2
- FLAD1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 40/190 reads (21%) | PolyPhen benign (0); catalogued as rs1558072150; called by muse, mutect2, varscan2
- FSHR | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58638788; called by muse, mutect2, varscan2
- GPR155 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 37/622 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762888833, COSV55039966, COSV99789740; called by muse, mutect2
- HEATR6 | c.2830A>G p.I944V | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs375489410; called by muse, mutect2, varscan2
- HELZ2 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs779218612; called by muse, mutect2, varscan2
- INTS13 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53903939, COSV53904242; called by muse, mutect2
- KCNMB1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99211694; called by muse, mutect2, varscan2
- KCNMB3 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 18/408 reads (4%) | catalogued as COSV58571483; called by muse, mutect2
- KIAA1217 | c.1336A>G p.M446V | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.959); catalogued as rs763699546; called by muse, mutect2, varscan2
- MLLT6 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs1230317780; called by muse, mutect2, varscan2
- NEUROD1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV99716769; called by muse, mutect2
- OBSCN | c.5296G>C p.E1766Q | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.721); catalogued as COSV52744958; called by muse, mutect2
- OR10G7 | c.242T>C p.M81T | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as rs770247308; called by muse, mutect2, varscan2
- OR2T1 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs142206098; called by muse, mutect2
- OR5K1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs988947469, COSV60303968; called by muse, mutect2, varscan2
- PCF11 | c.1591A>G p.M531V | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1310585039; called by muse, mutect2, varscan2
- PRDM4 | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.094); catalogued as COSV99946329; called by muse, mutect2
- PSME3IP1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs1429538464; called by muse, mutect2
- PTEN | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64311385; called by muse, mutect2, varscan2
- RBM19 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1186886571; called by muse, mutect2
- RNF39 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV54992892; called by muse, mutect2
- TAS2R40 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs374345239; called by muse, mutect2, varscan2
- TRAFD1 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs777245645; called by muse, mutect2, varscan2
- UNC45B | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs148629409, COSV52097677; called by muse, mutect2, varscan2
- UPB1 | c.459+2T>C p.X153_splice | Splice Site (SNP) | VAF 76/553 reads (14%) | catalogued as rs750705397; called by muse, mutect2, varscan2
- VPS52 | c.1567A>G p.I523V | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as rs1261222956; called by muse, mutect2, varscan2
- WDR72 | c.2781-2A>G p.X927_splice | Splice Site (SNP) | VAF 21/120 reads (18%) | catalogued as rs943319746; called by muse, mutect2, varscan2
- ZNF696 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1377057538; called by muse, mutect2
- ANKRD30A | c.1817G>T p.G606V (on ENST00000611781; = p.G550V on NM_052997.2) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- APEX1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 146/546 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ARHGEF1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ASCC3 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP3 | c.1228T>A p.C410S | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CA8 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CALR | c.774_777del p.D258Efs*7 | Frame Shift Del (DEL) | VAF 92/677 reads (14%) | called by mutect2, pindel, varscan2
- CASC3 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.527); called by muse, mutect2
- CD244 | c.1054G>T p.A352S (on ENST00000368033 / NM_001166663.2; = p.A347S on NM_016382.4) | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CDADC1 | c.1466G>C p.R489T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDH19 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.4261C>G p.L1421V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.141); called by muse, mutect2
- CPSF1 | c.3595G>A p.E1199K | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CSMD1 | c.1408G>T p.G470C (on ENST00000520002; = p.G469C on NM_033225.6) | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCHS1 | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.992); called by muse, mutect2
- DDX3X | c.1796G>C p.R599T (on ENST00000399959; = p.R600T on NM_001356.5) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DIABLO | c.189C>G p.I63M (on ENST00000443649 / NM_001278303.1; = p.I136M on NM_019887.6) | Missense Mutation (SNP) | VAF 114/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAH10 | c.4357G>A p.E1453K (on ENST00000409039; = p.E1392K on NM_207437.3) | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH5 | c.10101+2T>C p.X3367_splice | Splice Site (SNP) | VAF 107/592 reads (18%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.2340T>A p.D780E | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- EXOC8 | c.1725G>C p.W575C | Missense Mutation (SNP) | VAF 24/529 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAM98C | c.556-8C>T | Splice Region (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- FOXN4 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- FRK | c.1502A>C p.N501T | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMD6 | c.1150C>T p.H384Y (on ENST00000344768 / NM_001267046.2; = p.H376Y on NM_152330.4) | Missense Mutation (SNP) | VAF 23/521 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.435); called by muse, mutect2
- GAB4 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GSK3A | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A2 | c.1585G>C p.G529R | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.3949G>T p.D1317Y | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.36); called by muse, mutect2
- HNRNPA0 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.41); called by muse, mutect2
- IARS1 | c.3157C>T p.L1053F | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, varscan2
- LAMA5 | c.4736G>C p.C1579S | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LGALS8 | c.668C>G p.S223* (on ENST00000341872; = p.S265* on NM_006499.4) | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- LMBR1 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MBD3L3 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 151/1122 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MINK1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- MUC16 | c.16432C>G p.Q5478E | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); called by muse, mutect2
- NBEA | c.7397A>T p.D2466V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.2207+1G>T p.X736_splice | Splice Site (SNP) | VAF 149/360 reads (41%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 219/964 reads (23%) | called by muse, mutect2, varscan2
- PCGF5 | c.693A>T p.Q231H | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD11 | c.3706C>T p.R1236* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- PDE12 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PIGG | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PLCG2 | c.1706_1707del p.F569Sfs*3 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- PLD5 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- PLEKHA2 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- POC5 | c.920G>C p.R307T (on ENST00000428202 / NM_001099271.2; = p.R282T on NM_152408.2) | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PPARGC1A | c.1633T>A p.S545T | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PPP6R2 | c.1858G>C p.E620Q (on ENST00000216061 / NM_001365836.1; = p.E593Q on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRICKLE2 | c.274G>C p.E92Q (on ENST00000295902; = p.E36Q on NM_198859.4) | Missense Mutation (SNP) | VAF 70/720 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB11FIP4 | c.1095G>C p.K365N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, varscan2
- RIC8A | c.1585G>C p.D529H (on ENST00000526104 / NM_001286134.1; = p.D535H on NM_021932.5) | Missense Mutation (SNP) | VAF 78/904 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- RPS15 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 58/876 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- SCUBE1 | c.450T>A p.S150R | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SETD3 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SLC4A5 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- SNX17 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOS2 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SREK1IP1 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2
- SSU72P8 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAAR1 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM184A | c.215_219+7del p.X72_splice | Splice Site (DEL) | VAF 39/156 reads (25%) | called by mutect2, pindel, varscan2
- TNFRSF11B | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TNPO1 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TTN | c.5905G>A p.D1969N (on ENST00000591111; = p.D1923N on NM_003319.4) | Missense Mutation (SNP) | VAF 109/651 reads (17%) | PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- UNC13C | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZBTB47 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H12A | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM8 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ATRX | c.6534G>T p.R2178= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs782771702; called by muse, mutect2, varscan2
- BDP1 | c.5250T>G p.G1750= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV62430848; called by muse, mutect2, varscan2
- CCPG1 | c.2160A>C p.G720= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- CDH1 | c.378G>A p.P126= | Silent (SNP) | VAF 65/340 reads (19%) | catalogued as rs786201504; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH16 | c.504G>C p.L168= | Silent (SNP) | VAF 21/246 reads (9%) | catalogued as COSV55339329; called by muse, mutect2
- CHST6 | c.861C>G p.L287= | Silent (SNP) | VAF 48/1070 reads (4%) | called by muse, mutect2
- CNOT3 | c.2139G>A p.K713= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- CYP2E1 | c.1134C>T p.F378= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV53313398; called by muse, mutect2
- FASN | c.3966C>T p.L1322= | Silent (SNP) | VAF 127/545 reads (23%) | catalogued as rs765948097; called by muse, mutect2, varscan2
- FHAD1 | c.1521G>A p.A507= | Silent (SNP) | VAF 43/215 reads (20%) | catalogued as rs1017876347; called by muse, mutect2, varscan2
- FRG2C | c.165C>T p.H55= | Silent (SNP) | VAF 70/960 reads (7%) | catalogued as rs1306649522; called by muse, mutect2
- GP6 | c.624C>T p.T208= | Silent (SNP) | VAF 116/571 reads (20%) | called by muse, mutect2, varscan2
- GPC5 | c.693G>C p.L231= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV65633142; called by muse, mutect2, varscan2
- H1-3 | c.315C>T p.S105= | Silent (SNP) | VAF 84/417 reads (20%) | catalogued as rs776308039; called by muse, mutect2, varscan2
- HSPA1A | c.1755C>T p.T585= | Silent (SNP) | VAF 157/792 reads (20%) | catalogued as rs773596627; called by muse, mutect2, varscan2
- HSPA9 | c.1935G>C p.L645= | Silent (SNP) | VAF 40/540 reads (7%) | called by muse, mutect2
- NKX2-1 | c.465G>A p.P155= | Silent (SNP) | VAF 190/704 reads (27%) | catalogued as rs562374959; called by muse, mutect2, varscan2
- NLRC5 | c.2715C>T p.L905= | Silent (SNP) | VAF 56/346 reads (16%) | called by muse, mutect2, varscan2
- NSD1 | c.7149C>T p.G2383= | Silent (SNP) | VAF 68/268 reads (25%) | called by muse, mutect2, varscan2
- OR2T1 | c.186C>T p.L62= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV63542748; called by muse, mutect2
- PARP8 | c.1152A>G p.L384= | Silent (SNP) | VAF 59/255 reads (23%) | catalogued as rs369809692; called by muse, mutect2, varscan2
- PCDHB13 | c.1920G>A p.L640= | Silent (SNP) | VAF 32/980 reads (3%) | catalogued as rs782606651; called by muse, mutect2
- POU4F3 | c.429G>A p.Q143= | Silent (SNP) | VAF 25/650 reads (4%) | called by muse, mutect2
- RPH3AL | c.174C>T p.V58= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- SOX12 | c.129G>A p.P43= | Silent (SNP) | VAF 43/574 reads (7%) | called by muse, mutect2
- SPNS1 | c.1422C>T p.G474= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs1026655132; called by muse, mutect2, varscan2
- SRPK1 | c.1668G>A p.G556= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs541883939; called by muse, mutect2, varscan2
- TMEM39B | c.990C>T p.T330= | Silent (SNP) | VAF 122/487 reads (25%) | called by muse, mutect2, varscan2
- TRIM5 | c.684G>C p.L228= | Silent (SNP) | VAF 43/169 reads (25%) | called by muse, mutect2, varscan2
- TRPM3 | c.4893C>T p.I1631= (on ENST00000357533 / NM_001366142.2; = p.I1486= on NM_020952.6) | Silent (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- USP44 | c.1710C>T p.L570= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV51567939; called by muse, mutect2, varscan2
- WRNIP1 | c.738G>T p.V246= | Silent (SNP) | VAF 62/268 reads (23%) | called by muse, mutect2, varscan2
- AK2 | c.*3113dup | 3'UTR (INS) | VAF 96/511 reads (19%) | called by mutect2, varscan2
- ATP8B1 | c.2209+26del | Intron (DEL) | VAF 74/252 reads (29%) | called by mutect2, pindel, varscan2
- C5orf60 | n.2301G>A | RNA (SNP) | VAF 138/602 reads (23%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+516C>A | Intron (SNP) | VAF 30/514 reads (6%) | called by muse, mutect2
- COMMD4 | c.75+110C>A | Intron (SNP) | VAF 28/216 reads (13%) | called by muse, mutect2
- GULP1 | c.-172+4405A>T | Intron (SNP) | VAF 24/225 reads (11%) | catalogued as rs1228982169; called by muse, mutect2, varscan2
- HIPK1 | c.3144+50C>G | Intron (SNP) | VAF 61/244 reads (25%) | called by muse, mutect2, varscan2
- IQSEC1 | c.*13G>T | 3'UTR (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- SH3GLB2 | c.335-894C>T | Intron (SNP) | VAF 44/90 reads (49%) | catalogued as rs1304628926; called by muse, mutect2, varscan2
- SHCBP1L | c.858-12G>T | Intron (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- SNAPC5 | c.90+46G>A | Intron (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- TSC2 | c.336+353C>T | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- ZFYVE19 | c.-164G>C | 5'UTR (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+194C>G | Intron (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
